Somatic mutation profile of tumor specimen TCGA-A6-6654-01A (aliquot TCGA-A6-6654-01A-21D-1835-10) from TCGA case TCGA-A6-6654, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.6 years (23,953 days).
Specimen TCGA-A6-6654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93ddcfd7-590d-47a9-b568-0527ce4e79d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6654-10A (Blood Derived Normal), aliquot TCGA-A6-6654-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcd27fc6-4752-4943-9b2f-0c93d4abfb08

The open-access MAF lists 208 somatic variants for this specimen: 143 protein-altering or splice-affecting, 61 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 61, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, Intron 2, RNA 2, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IFIH1 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587777448, CM144546, COSV55125315; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 30/155 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- AATK | c.2095G>A p.V699I (on ENST00000326724 / NM_001080395.3; = p.V596I on NM_004920.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1415647040, COSV100353246; called by mutect2, varscan2
- ALDH1A3 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60901127; called by muse, mutect2, varscan2
- AP3B2 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754527481, COSV55607487; called by muse, mutect2, varscan2
- APBA2 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752622045, COSV101258138, COSV67104392; called by muse, mutect2, varscan2
- ARHGEF11 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.865); catalogued as rs368227122; called by muse, mutect2, varscan2
- ARHGEF7 | c.1303C>A p.Q435K (on ENST00000375741 / NM_001113511.2; = p.Q257K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.345); catalogued as COSV99522103; called by muse, mutect2, varscan2
- ATP4A | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1355489531, COSV52870593; called by muse, mutect2, varscan2
- ATP8A1 | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs375992978; called by muse, mutect2, varscan2
- BCL11A | c.1654G>A p.D552N (on ENST00000335712 / NM_001365609.1; = p.D586N on NM_018014.4) | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as COSV59626183; called by muse, mutect2, varscan2
- BRF1 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59267787; called by muse, mutect2, varscan2
- BTNL8 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs1203585455, COSV51457556; called by muse, mutect2, varscan2
- CACNB4 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52390262, COSV52390706; called by muse, mutect2, varscan2
- CALCR | c.1133G>A p.R378K (on ENST00000649521 / NM_001164737.2; = p.R362K on NM_001742.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as COSV64006652; called by muse, mutect2
- CAVIN3 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as COSV58268715; called by muse, mutect2, varscan2
- CD248 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs140856103; called by muse, mutect2, varscan2
- CEP164 | c.3989C>T p.T1330M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs774641136, COSV54038423; called by muse, mutect2, varscan2
- CEP95 | c.252A>G p.I84M | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56748378; called by muse, mutect2, varscan2
- CHST5 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs572591635, COSV60337870; called by muse, mutect2, varscan2
- CLEC16A | c.1576G>A p.V526M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as rs200389848, COSV68498531; called by muse, mutect2, varscan2
- CLUH | c.1172C>T p.A391V (on ENST00000435359; = p.A429V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs761016997, COSV70928158; called by muse, mutect2, varscan2
- COL6A2 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201792591, COSV100154215, COSV56015166; ClinVar: uncertain significance; called by mutect2, varscan2
- CPSF2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs892281737, COSV54100584; called by muse, mutect2
- CPXM2 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs769337470, COSV99582422; called by muse, mutect2, varscan2
- CYP1B1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs761627618, COSV53190933; called by muse, mutect2, varscan2
- DCAF12L2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV63580780; called by muse, mutect2, varscan2
- DCHS1 | c.7756G>A p.V2586M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs747141130, COSV54996502; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749290262, COSV62567043; called by muse, mutect2, varscan2
- EFL1 | c.2332del p.Q778Sfs*2 | Frame Shift Del (DEL) | VAF 23/111 reads (21%) | catalogued as COSV51603623; called by mutect2, pindel, varscan2
- ELANE | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs201313263, COSV55047716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA1 | c.936T>A p.N312K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV58158890; called by muse, mutect2
- FAM47C | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs782568130, COSV63724764; called by muse, mutect2, varscan2
- FILIP1 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as rs775141616, COSV52724965; called by muse, mutect2, varscan2
- FNBP1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs374562503; called by muse, mutect2, varscan2
- GABBR1 | c.2024G>A p.S675N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63541560; called by muse, mutect2, varscan2
- GAD2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52152616; called by muse, mutect2
- GALNT9 | c.1327C>T p.R443C (on ENST00000328957 / NM_001122636.2; = p.R77C on NM_021808.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs769224342, COSV61096889; called by muse, mutect2, varscan2
- GMEB2 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99823860; called by muse, mutect2, varscan2
- GORAB | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1181765739, COSV100883873; called by muse, mutect2
- GPC5 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV65584940; called by muse, mutect2, varscan2
- GPR157 | c.1002C>A p.S334R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV101072594; called by muse, mutect2, varscan2
- GRIN1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1261706375, COSV59293690; called by muse, mutect2, varscan2
- H2AC1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs371440858; called by mutect2, varscan2
- HDGFL1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.046); catalogued as rs534951625, COSV100014538; called by mutect2, varscan2
- HLTF | c.2228A>G p.K743R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100027123; called by muse, mutect2, varscan2
- HSD3B1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs765077190, COSV52489793, COSV52491178; called by muse, mutect2, varscan2
- IFNG | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs1476472852, COSV57490876; called by muse, mutect2, varscan2
- IKZF4 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56267300; called by muse, mutect2, varscan2
- IL16 | c.1979G>T p.C660F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV57261545; called by muse, mutect2, varscan2
- KASH5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199889676; called by muse, mutect2, varscan2
- KCNK18 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs777087206, COSV57971266; called by muse, mutect2, varscan2
- KIAA1217 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374089576; called by muse, mutect2, varscan2
- KLHL1 | c.1703A>G p.N568S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as COSV100918120; called by muse, mutect2, varscan2
- KMT2A | c.11794C>T p.R3932C | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63283385; called by muse, mutect2, varscan2
- KRT36 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV60202773; called by muse, mutect2, varscan2
- KRTAP1-5 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as rs769945912, COSV100721405; called by muse, mutect2, varscan2
- LCE2C | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.342); catalogued as rs561716750, COSV64228338; called by muse, mutect2, varscan2
- LEO1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs767042967, COSV55175071; called by muse, mutect2, varscan2
- LRRC74A | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV99372736; called by muse, mutect2, varscan2
- LTBP3 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV57242837; called by muse, mutect2, varscan2
- MAMDC2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.215); catalogued as rs147526021; called by muse, mutect2, varscan2
- MARK2 | c.1279A>G p.T427A (on ENST00000402010 / NM_001039469.2; = p.T426A on NM_004954.5) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100159145; called by muse, mutect2, varscan2
- MED12 | c.4358A>C p.K1453T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV61334801; called by muse, mutect2, varscan2
- MINDY2 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764573238, COSV100376585; called by muse, mutect2, varscan2
- MMP13 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs767829684, COSV52823318; called by muse, mutect2, varscan2
- MMP17 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.189); catalogued as rs760432391, COSV62178594; called by mutect2, varscan2
- MMP9 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as COSV100812462; called by muse, mutect2, varscan2
- MPO | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99833014; called by muse, mutect2, varscan2
- MROH7 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs745384704, COSV59869259; called by muse, mutect2, varscan2
- MYO18B | c.4415G>A p.R1472Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs771738416, COSV59128718; called by muse, mutect2, varscan2
- MYO1B | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1310398313, COSV100270041, COSV58429880; called by muse, mutect2
- MYO9B | c.5225G>A p.R1742H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs572226847, COSV68277778; called by muse, mutect2, varscan2
- NCF1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.551); catalogued as rs1342608126, COSV99194322; called by muse, mutect2, varscan2
- NEB | c.16901C>T p.T5634M | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767584361, COSV50857518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOL6 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs144030112; called by muse, mutect2, varscan2
- NRXN1 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60508639; called by muse, mutect2
- NRXN1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV68007020; called by muse, mutect2
- NT5C1A | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539519081, COSV52495974, COSV52497301; called by muse, mutect2, varscan2
- OR2M2 | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV62897969; called by muse, mutect2, varscan2
- OSBPL7 | c.2429C>T p.T810M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as rs761063588, COSV50107464; called by muse, mutect2, varscan2
- OTOP1 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as COSV56391632; called by muse, mutect2, varscan2
- P2RX2 | c.969C>G p.I323M (on ENST00000343948 / NM_170683.4; = p.I251M on NM_012226.5) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57676336, COSV57678506; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.652C>G p.L218V (on ENST00000259318 / NM_001136562.3; = p.L449V on NM_007203.5) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776011217, COSV99395723; called by muse, mutect2, varscan2
- PASK | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs556062263, COSV52149341; called by muse, mutect2, varscan2
- PAX3 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as rs770087251, CD102011, COSV60586905; called by muse, mutect2, varscan2
- PCDHA1 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs1306684678, COSV65375859; called by muse, mutect2, varscan2
- PCDHA12 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1554168680, COSV56482309; called by muse, mutect2, varscan2
- PCDHB13 | c.2162C>T p.S721L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs782075083, COSV53396113; called by muse, mutect2, varscan2
- PCDHGB1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749871543, COSV53915242; called by muse, mutect2, varscan2
- PCLO | c.11537G>C p.R3846P | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61622735, COSV61628919; called by muse, mutect2
- PCSK2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs767747613, COSV52728215; called by muse, mutect2, varscan2
- PDCL3 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs750858703, COSV51808903; called by muse, mutect2, varscan2
- PDGFRB | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs780819031, COSV55802527; called by muse, mutect2, varscan2
- PDLIM5 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs201891054; called by muse, mutect2, varscan2
- PELI1 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1187489333, COSV62729693; called by muse, mutect2, varscan2
- PHLPP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs968349190, COSV62423342; called by muse, mutect2, varscan2
- PIK3R6 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.148); catalogued as COSV100266859; called by muse, mutect2, varscan2
- PLXNA4 | c.4264C>T p.H1422Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58112621; called by muse, varscan2
- PSMA8 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57601510; called by muse, mutect2, varscan2
- PSMB7 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149845424; called by mutect2, varscan2
- RAB34 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs894000336, COSV56385622; called by muse, mutect2, varscan2
- RBMS1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV62351428; called by muse, mutect2, varscan2
- RNF20 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs755745298, COSV101206581; called by muse, mutect2, varscan2
- RRP12 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs201494564; called by muse, mutect2, varscan2
- RSPO2 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs747227279, COSV52640302, COSV52640655; called by muse, mutect2, varscan2
- RTP1 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as rs749446967, COSV56617641; called by mutect2, varscan2
- SDCBP2 | c.616G>A p.V206M (on ENST00000339987 / NM_001199784.1; = p.V121M on NM_015685.5) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs762408353, COSV60588511; called by muse, mutect2, varscan2
- SERPINB7 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.092); catalogued as rs751578467, COSV60533016; called by muse, mutect2, varscan2
- SH3PXD2A | c.1603G>A p.E535K (on ENST00000369774 / NM_001365079.1; = p.E507K on NM_014631.2) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as rs1300843206, COSV60116305; called by muse, mutect2, varscan2
- SLC1A3 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229578292, COSV54314880, COSV99468288; called by muse, mutect2, varscan2
- SLC9A9 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs771359670, COSV57221558; called by muse, mutect2, varscan2
- SMC1B | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs200460572, COSV62531884; called by muse, mutect2, varscan2
- SMG8 | c.2563C>T p.R855* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV56284475; called by muse, mutect2, varscan2
- SPINDOC | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs750643253, COSV53692141; called by muse, mutect2, varscan2
- SVOP | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765709664, COSV100139648; called by muse, mutect2, varscan2
- SYT3 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs779504372, COSV58895825; called by muse, mutect2, varscan2
- TAZ | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54795974; called by muse, mutect2, varscan2
- TBC1D5 | c.1585A>T p.K529* | Nonsense Mutation (SNP) | VAF 17/136 reads (13%) | catalogued as COSV53751971; called by muse, mutect2
- TBL1XR1 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV61789762; called by muse, mutect2, varscan2
- TEAD3 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV58816105; called by muse, mutect2, varscan2
- TEX101 | c.233C>T p.T78M (on ENST00000598265 / NM_001130011.3; = p.T96M on NM_031451.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs145466151; called by muse, mutect2, varscan2
- THAP4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs775668991, COSV67190897; called by mutect2, varscan2
- TSR3 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.732); catalogued as rs149957870; called by muse, mutect2, varscan2
- TUBA3C | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); catalogued as rs1377606600, COSV67138991; called by muse, mutect2, varscan2
- TYRO3 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs760003502, COSV55481841; called by muse, mutect2, varscan2
- VASH1 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs756346135, COSV51335459, COSV51340487; called by muse, mutect2, varscan2
- VWA2 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs569122106, COSV53905472; called by muse, mutect2, varscan2
- ZC3H12C | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs755763390, COSV53707232; called by muse, mutect2, varscan2
- ZDHHC8 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs372406851; called by muse, mutect2, varscan2
- ZNF337 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs369445290; called by muse, mutect2, varscan2
- ZNF454 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1021248473, COSV60766845, COSV60768682; called by muse, mutect2
- ZNF497 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV54052307; called by muse, mutect2
- ZNF521 | c.3319A>C p.I1107L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100833359; called by muse, mutect2, varscan2
- ARID2 | c.1765_1767dup p.N589dup | In Frame Ins (INS) | VAF 29/98 reads (30%) | called by mutect2, varscan2
- ASPM | c.3185_3189del p.N1062Rfs*28 | Frame Shift Del (DEL) | VAF 18/198 reads (9%) | called by mutect2, pindel
- CTR9 | c.722_723insGTTGT p.E242Lfs*2 | Frame Shift Ins (INS) | VAF 8/81 reads (10%) | called by muse*, mutect2
- FILIP1L | c.649_651del p.K217del | In Frame Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- HYDIN | c.5956dup p.I1986Nfs*6 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- MKI67 | c.954del p.K319Rfs*27 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- ZSCAN18 | c.261dup p.M88Dfs*16 | Frame Shift Ins (INS) | VAF 12/83 reads (14%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3036G>A p.T1012= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs751467717, COSV60682255; called by muse, mutect2, varscan2
- AEBP1 | c.2295C>T p.G765= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1319004498, COSV56256173; called by muse, mutect2, varscan2
- BTNL2 | c.669C>T p.P223= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1234067846, COSV66630403; called by muse, mutect2, varscan2
- CA13 | c.189C>T p.S63= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs548734922, COSV58797229; called by muse, mutect2
- CCDC114 | c.1893C>T p.S631= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs181011260; called by muse, mutect2, varscan2
- CDH4 | c.297G>A p.A99= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs79132902; called by muse, mutect2, varscan2
- CDV3 | c.336C>T p.D112= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs140108131; called by muse, mutect2, varscan2
- CHMP2A | c.93C>T p.R31= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as COSV53396553; called by muse, mutect2
- CNTNAP4 | c.2991A>C p.S997= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56670108; called by muse, mutect2
- CORO1B | c.477C>T p.I159= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV58168520; called by muse, mutect2, varscan2
- CTR9 | c.3063G>A p.S1021= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs182230438, COSV63727850; called by muse, mutect2, varscan2
- CYP17A1 | c.909C>T p.G303= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs563749393, COSV100882137, COSV64004782; called by muse, mutect2, varscan2
- CYP2A6 | c.297C>T p.S99= | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as rs777681590, COSV99992162; called by muse, mutect2, varscan2
- DCAF4L2 | c.573C>T p.S191= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100151120, COSV60483769; called by muse, mutect2
- DMBX1 | c.918C>T p.G306= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs772919371, COSV100760910; called by mutect2, varscan2
- DMPK | c.516G>A p.A172= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs748808453, COSV99353672; called by mutect2, varscan2
- DOCK7 | c.6039G>A p.Q2013= (on ENST00000635253 / NM_001367561.1; = p.Q1982= on NM_033407.3) | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as COSV51999398; called by muse, mutect2, varscan2
- DUSP10 | c.21C>T p.D7= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs546322180, COSV60456904; called by muse, mutect2, varscan2
- DYSF | c.2829C>T p.D943= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs143775913; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGLN2 | c.576C>T p.C192= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs781201989, COSV58279552; called by mutect2, varscan2
- ESRRB | c.1191G>A p.P397= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs746427886, COSV99835760; called by muse, mutect2, varscan2
- FIBCD1 | c.834C>T p.D278= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs769557055, COSV53394573; called by mutect2, varscan2
- FMO4 | c.1032C>G p.L344= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV63000740, COSV63001530; called by muse, mutect2, varscan2
- FN1 | c.3399A>T p.S1133= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV100118641, COSV60548493; called by muse, mutect2, varscan2
- FUZ | c.87C>T p.R29= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV58241006; called by muse, mutect2, varscan2
- GDF7 | c.1227G>A p.A409= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs1182817522, COSV55347665; called by muse, mutect2
- GFPT2 | c.618C>T p.I206= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs532764596, COSV99518077; called by mutect2, varscan2
- IFI44L | c.906G>A p.E302= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs1185516714, COSV60727003; called by muse, mutect2
- IGSF5 | c.837G>A p.P279= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs200284688, COSV66029614; called by muse, mutect2, varscan2
- IMPG1 | c.234T>C p.V78= | Silent (SNP) | VAF 28/238 reads (12%) | catalogued as COSV64055333; called by muse, mutect2, varscan2
- ISLR2 | c.1833C>T p.A611= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- KCTD10 | c.315C>T p.I105= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs758410649, COSV57326219; called by muse, mutect2, varscan2
- KIF21B | c.2907C>T p.P969= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs749368413, COSV59754297; called by muse, mutect2, varscan2
- KLHDC7A | c.2262G>A p.P754= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs760748321, COSV68769239; called by muse, mutect2, varscan2
- KRT31 | c.1128C>T p.N376= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as rs989802341, COSV52433550; called by muse, mutect2
- LMTK3 | c.2055G>A p.R685= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- MAEA | c.138C>T p.H46= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs751359580, COSV53261694; called by muse, mutect2, varscan2
- MDGA1 | c.846G>T p.L282= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV51793333, COSV99776709; called by muse, mutect2, varscan2
- NCOR1 | c.3171C>T p.I1057= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs368943561, COSV51971511; called by muse, varscan2
- NINL | c.165C>T p.N55= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs374578020; called by muse, mutect2, varscan2
- NLRC5 | c.5073G>A p.R1691= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs752220305, COSV52651137; called by mutect2, varscan2
- P2RY8 | c.783C>T p.I261= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV101184058, COSV67176705, COSV67176831; called by muse, mutect2, varscan2
- PDE1B | c.747G>A p.S249= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs113265707; called by muse, mutect2, varscan2
- PDZRN4 | c.1332C>T p.D444= (on ENST00000402685 / NM_001164595.2; = p.D186= on NM_013377.4) | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs746718521, COSV54195464; called by muse, mutect2, varscan2
- PIKFYVE | c.1140G>A p.T380= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs750959225, COSV52237589; called by muse, mutect2, varscan2
- PROSER2 | c.459G>A p.P153= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs779812074, COSV53204764; called by muse, mutect2, varscan2
- RPA2 | c.423G>A p.L141= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100536296; called by muse, mutect2
- SALL2 | c.63G>A p.A21= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1372180419, COSV58102510; called by muse, mutect2, varscan2
- SAXO2 | c.57G>A p.S19= | Silent (SNP) | VAF 35/187 reads (19%) | catalogued as rs200016551, COSV59753610; called by muse, mutect2, varscan2
- SEC14L1 | c.1431C>T p.Y477= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV66721261; called by muse, mutect2, varscan2
- SEL1L2 | c.1224C>T p.D408= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs529645967, COSV53149299; called by muse, mutect2, varscan2
- SIGLEC8 | c.1161C>T p.C387= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs754706683, COSV58472742; called by muse, mutect2, varscan2
- SLC2A10 | c.675C>T p.R225= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs954404406, COSV63713960; called by muse, mutect2, varscan2
- SLC44A3 | c.1866A>G p.V622= (on ENST00000271227 / NM_001114106.3; = p.V574= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as COSV54728395; called by muse, mutect2, varscan2
- SRCIN1 | c.525C>T p.A175= (on ENST00000621492; = p.A141= on NM_025248.3) | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2
- ST6GALNAC5 | c.375C>T p.D125= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs919395133, COSV59561977; called by muse, mutect2, varscan2
- SUCLG2 | c.495C>T p.P165= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs200035351, COSV56202271; called by muse, mutect2, varscan2
- TNC | c.3597G>T p.V1199= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs764479295, COSV60782052; called by mutect2, varscan2
- USH2A | c.357C>T p.N119= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs562750831, COSV56341067; called by muse, mutect2
- WDFY3 | c.7902A>G p.G2634= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99885602; called by muse, mutect2, varscan2
- ZNF282 | c.717G>A p.A239= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs367801148; called by muse, mutect2, varscan2
- MIR1283-2 | n.58G>A | RNA (SNP) | VAF 6/49 reads (12%) | catalogued as rs374675598; called by mutect2, varscan2
- MIR519D | n.40T>C | RNA (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- NAA38 | c.81+78G>A | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as COSV54679075; called by muse, mutect2, varscan2
- RGPD1 | c.48+5840C>T | Intron (SNP) | VAF 30/90 reads (33%) | catalogued as rs764224426, COSV67962719; called by muse, mutect2, varscan2
